Gene-level copy-number profile of tumor specimen ALCH-B0CP-TTP1-A from ALCHEMIST case ALCH-B0CP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.6 years (23,581 days).
Specimen ALCH-B0CP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 89575ab0-3eb3-465c-9bf9-f02a31facf12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,760 have no estimate.
https://portal.gdc.cancer.gov/files/a8e7d202-3482-41c5-ade0-df36cdeb9571

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 946; copy number 2: 20,116; copy number 3: 15,628; copy number 4: 11,285; copy number 5: 7,715; copy number 6: 1,474; copy number 7: 204; copy number 8: 103; copy number 9: 493; copy number 10: 123; copy number 11: 8; copy number 13: 45; copy number 14: 42; copy number 25: 5; copy number 26: 4; copy number 32: 14; copy number 34: 74; copy number 42: 18; copy number 43: 34; copy number 48: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:232,520,388–232,525,716, 1 gene: PRSS56.
- chr9:42,183,659–42,569,353, 12 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,286 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 9 genes, copy number 5–25 (within-gene range 1–25): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, OR4G4P, OR4G11P, OR4F5, AL627309.1.
- chr1:131,025–686,673, 24 genes, copy number 5–7 (within-gene range 4–7): CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, OR4F16.
- chr1:143,419,625–189,133,292, 1,334 genes, copy number 5–7 (broad region; genes not listed).
- chr2:38,814–15,680,484, 228 genes, copy number 5 (broad region; genes not listed).
- chr2:15,864,935–25,342,590, 147 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:25,377,198–194,188,309, 2,762 genes, copy number 5 (broad region; genes not listed).
- chr3:93,843,764–95,172,377, 15 genes, copy number 6: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6.
- chr3:111,674,676–111,846,447, 1 gene, copy number 5 (within-gene range 3–5): PLCXD2.
- chr3:111,732,497–111,993,368, 3 genes, copy number 5: PHLDB2, AC117509.1, ABHD10.
- chr3:132,558,138–136,147,894, 54 genes, copy number 6: ACAD11, NPHP3-ACAD11, ACKR4, HSPA8P19, UBA5, NPHP3, NPHP3-AS1, AC079942.1, TMEM108, TMEM108-AS1, BFSP2, AC055753.1, BFSP2-AS1, AC022296.2, AC022296.4, AC022296.3, AC022296.1, CDV3, TOPBP1, INHCAP, RNU6-678P, RNA5SP140, TF, AC080128.1, SRPRB, AC080128.2, RAB6B, C3orf36, SLCO2A1, LINC02000, RYK, HMGB3P14, LINC02004, AC010207.1, RPL39P5, AMOTL2, MIR6827, HMGN1P9, HMGB3P13, MIR4788, ANAPC13, CEP63, AC026117.1, EPHB1, KY, AC016931.1, RNU6-1174P, RNA5SP141, AC092969.1, AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2.
- chr3:139,837,220–141,367,753, 19 genes, copy number 6 (within-gene range 4–6): AC016933.1, TRMT112P5, CLSTN2, AC010181.1, AC010181.2, CLSTN2-AS1, AC048346.1, TRIM42, AC121333.1, RPL23AP41, SLC25A36, AC108727.1, SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2.
- chr3:142,157,527–168,095,924, 367 genes, copy number 6 (broad region; genes not listed).
- chr3:168,902,194–198,123,232, 578 genes, copy number 5–48 (broad region; genes not listed).
- chr4:48,341,529–49,246,915, 19 genes, copy number 8: SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4, AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22.
- chr4:51,843,000–57,495,844, 119 genes, copy number 5–7 (broad region; genes not listed).
- chr4:180,573,464–180,574,027, 1 gene, copy number 5: NDUFB5P1.
- chr5:58,198–1,523,962, 54 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075.
- chr5:9,546,200–23,689,386, 189 genes, copy number 5–6 (broad region; genes not listed).
- chr5:27,217,714–45,895,970, 269 genes, copy number 6 (broad region; genes not listed).
- chr5:53,413,504–55,096,553, 29 genes, copy number 7: AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1.
- chr5:63,022,919–63,023,489, 1 gene, copy number 6: AC113420.1.
- chr6:485,154–23,649,774, 351 genes, copy number 6 (broad region; genes not listed).
- chr7:63,209,219–67,770,468, 189 genes, copy number 5 (broad region; genes not listed).
- chr7:142,645,961–142,793,368, 24 genes, copy number 6 (within-gene range 4–6): TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 6: TRBC2.
- chr7:150,433,654–150,861,504, 20 genes, copy number 5: LINC00996, GIMAP8, AC073111.1, STRADBP1, GIMAP7, ALDH7A1P3, GIMAP4, AC069304.3, AC069304.1, GIMAP6, AC069304.2, GIMAP2, GIMAP1, GIMAP1-GIMAP5, GIMAP5, GIMAP3P, BET1P1, TMEM176B, TMEM176A, AOC1.
- chr7:158,590,629–159,233,377, 11 genes, copy number 6–9: LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr11:34,915,829–35,020,591, 1 gene, copy number 5 (within-gene range 4–5): PDHX.
- chr11:77,216,558–83,423,516, 92 genes, copy number 5 (broad region; genes not listed).
- chr11:94,021,354–94,114,208, 1 gene, copy number 5 (within-gene range 4–5): HEPHL1.
- chr11:94,128,841–107,738,718, 176 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:21,950,406–22,598,946, 114 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:19,061,912–21,704,612, 153 genes, copy number 7–11 (broad region; genes not listed).
- chr17:32,492,522–80,966,371, 1,668 genes, copy number 5 (within-gene range 4–6) (broad region; genes not listed).
- chr17:82,101,460–83,240,804, 55 genes, copy number 5: CCDC57, AC129510.1, AC129510.2, AC132872.2, SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL, AC130371.2, AC144831.1, AC139099.3, AC139099.2, AC139099.1, RPL23AP87.
- chr18:45,034–32,470,882, 558 genes, copy number 5–7 (broad region; genes not listed).
- chr18:63,647,579–63,726,432, 1 gene, copy number 5 (within-gene range 4–5): SERPINB11.
- chr19:925,781–1,086,628, 13 genes, copy number 5 (within-gene range 4–6): ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45.
- chr20:87,250–33,443,763, 632 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
